Somatic mutation profile of tumor specimen MMRF_1332_1_BM_CD138pos (aliquot MMRF_1332_1_BM_CD138pos_T1_KHS5U_L15102) from MMRF case MMRF_1332, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 33.0 years (12,044 days).
Specimen MMRF_1332_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4e341f86-387b-401c-a854-40da1f7a43b2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1332_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1332_1_PB_Whole_C2_KHS5U_L15101; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/818a3816-9467-49b0-999f-61ff427d8aee

The open-access MAF lists 75 somatic variants for this specimen: 33 protein-altering or splice-affecting, 9 silent, 33 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, 3'UTR 16, Silent 9, Intron 7, 5'Flank 5, 5'UTR 4, Nonsense Mutation 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASB2 | c.281T>G p.L94R | Missense Mutation (SNP) | VAF 40/42 reads (95%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60112831; called by muse, mutect2, varscan2
- DNAAF3 | c.508G>A p.V170I (on ENST00000524407 / NM_001256715.2; = p.V217I on NM_178837.4) | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.71); PolyPhen benign (0.007); catalogued as rs761802279; called by mutect2, varscan2
- H1-4 | c.635A>G p.K212R | Missense Mutation (SNP) | VAF 119/259 reads (46%) | SIFT tolerated (1); PolyPhen probably damaging (0.968); catalogued as COSV99175368; called by muse, mutect2, varscan2
- H2BC3 | c.110G>A p.S37N | Missense Mutation (SNP) | VAF 85/187 reads (45%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.006); catalogued as rs778158634, COSV63550870; called by muse, mutect2, varscan2
- IGHV2-70 | c.171G>A p.W57* | Nonsense Mutation (SNP) | VAF 81/88 reads (92%) | catalogued as rs370713802; called by muse, varscan2
- IGHV2-70 | c.131C>G p.S44C | Missense Mutation (SNP) | VAF 52/60 reads (87%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); catalogued as rs375225384; called by muse, varscan2
- IGHV2-70 | c.107C>T p.T36I | Missense Mutation (SNP) | VAF 38/44 reads (86%) | SIFT deleterious (0.02); PolyPhen benign (0.038); catalogued as rs548028630; called by muse, varscan2
- IGHV2-70 | c.49G>C p.V17L | Missense Mutation (SNP) | VAF 48/56 reads (86%) | SIFT deleterious (0.02); PolyPhen benign (0.206); catalogued as rs768517091; called by muse, varscan2
- IGKJ4 | c.29A>C p.E10A | Missense Mutation (SNP) | VAF 59/85 reads (69%) | PolyPhen possibly damaging (0.882); catalogued as rs185131270; called by muse, varscan2
- IGLL5 | c.82C>G p.L28V | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.08); catalogued as rs148489860, COSV73248966, COSV73250113; called by muse, mutect2, varscan2
- LAMA1 | c.7079G>A p.R2360H | Missense Mutation (SNP) | VAF 123/299 reads (41%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs141811330, COSV67539741, COSV67539971; called by muse, mutect2, varscan2
- LTB | c.198G>C p.Q66H | Missense Mutation (SNP) | VAF 150/316 reads (47%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as rs775344697, COSV59864281, COSV59865634; called by muse, mutect2
- MYO7A | c.2050C>T p.R684W | Missense Mutation (SNP) | VAF 60/142 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs782570489; called by muse, mutect2, varscan2
- SBNO2 | c.952C>T p.R318C | Missense Mutation (SNP) | VAF 101/181 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs757109846; called by muse, mutect2, varscan2
- SPINK14 | c.127G>A p.E43K | Missense Mutation (SNP) | VAF 97/220 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs774654382, COSV100810986; called by muse, mutect2, varscan2
- ZNF676 | c.269G>A p.G90D (on ENST00000650058; = p.G58D on NM_001001411.3) | Missense Mutation (SNP) | VAF 27/54 reads (50%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs769382326; called by muse, mutect2, varscan2
- ANK2 | c.9937A>C p.T3313P | Missense Mutation (SNP) | VAF 123/279 reads (44%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.277); called by muse, mutect2, varscan2
- CARMIL2 | c.710T>C p.I237T | Missense Mutation (SNP) | VAF 38/84 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.637); called by muse, mutect2, varscan2
- CNOT2 | c.1563A>T p.L521F | Missense Mutation (SNP) | VAF 160/351 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- DOCK2 | c.4728G>T p.Q1576H | Missense Mutation (SNP) | VAF 11/152 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- DOCK4 | c.3199A>G p.I1067V | Missense Mutation (SNP) | VAF 32/110 reads (29%) | SIFT tolerated (0.84); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DPH2 | c.1116G>A p.W372* | Nonsense Mutation (SNP) | VAF 8/217 reads (4%) | called by muse, mutect2
- EDEM1 | c.278G>T p.G93V | Missense Mutation (SNP) | VAF 49/99 reads (49%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- IGHV2-70D | c.301C>G p.L101V | Missense Mutation (SNP) | VAF 46/50 reads (92%) | SIFT deleterious (0.02); PolyPhen benign (0.011); called by muse, varscan2
- LAPTM4A | c.376G>A p.V126I | Missense Mutation (SNP) | VAF 92/188 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.334); called by muse, mutect2, varscan2
- MINPP1 | c.440T>C p.V147A | Missense Mutation (SNP) | VAF 119/248 reads (48%) | SIFT tolerated (0.24); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- NPR3 | c.602C>T p.A201V | Missense Mutation (SNP) | VAF 76/151 reads (50%) | SIFT tolerated (0.54); PolyPhen benign (0); called by muse, mutect2, varscan2
- PCDH7 | c.3127C>T p.H1043Y | Missense Mutation (SNP) | VAF 12/190 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.729); called by muse, mutect2
- SYBU | c.1550G>C p.S517T (on ENST00000276646 / NM_001099754.2; = p.S516T on NM_017786.6) | Missense Mutation (SNP) | VAF 79/178 reads (44%) | SIFT tolerated (0.23); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- TFE3 | c.559A>G p.T187A | Missense Mutation (SNP) | VAF 37/56 reads (66%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- UBE3A | c.407T>C p.I136T | Missense Mutation (SNP) | VAF 44/82 reads (54%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.91); called by muse, mutect2
- UGT2B11 | c.1574A>G p.K525R | Missense Mutation (SNP) | VAF 108/274 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- ZNF536 | c.3476A>C p.D1159A | Missense Mutation (SNP) | VAF 81/205 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ADCY2 | c.435C>T p.F145= | Silent (SNP) | VAF 137/282 reads (49%) | catalogued as rs765777716, COSV57869101; called by muse, mutect2, varscan2
- APBB3 | c.429C>T p.V143= | Silent (SNP) | VAF 54/102 reads (53%) | called by muse, mutect2, varscan2
- DNAH6 | c.4245C>T p.Y1415= | Silent (SNP) | VAF 85/287 reads (30%) | catalogued as rs199886756; called by muse, mutect2, varscan2
- DUSP2 | c.253C>T p.L85= | Silent (SNP) | VAF 26/47 reads (55%) | catalogued as rs551318349, COSV56620804; called by muse, mutect2, varscan2
- IGHV2-70D | c.30A>C p.L10= | Silent (SNP) | VAF 15/16 reads (94%) | called by mutect2, varscan2
- IGKV5-2 | c.63A>G p.E21= | Silent (SNP) | VAF 130/132 reads (98%) | catalogued as rs765604868; called by muse, mutect2, varscan2
- IGKV5-2 | c.207A>G p.Q69= | Silent (SNP) | VAF 134/138 reads (97%) | catalogued as rs537543055; called by muse, mutect2, varscan2
- NR1H4 | c.519T>C p.C173= (on ENST00000551379 / NM_001206993.2; = p.C163= on NM_005123.4) | Silent (SNP) | VAF 103/206 reads (50%) | called by muse, mutect2, varscan2
- PTMA | c.33A>G p.E11= | Silent (SNP) | VAF 52/115 reads (45%) | catalogued as rs1237491507; called by muse, varscan2
- ARHGAP44 | c.*400G>A | 3'UTR (SNP) | VAF 11/300 reads (4%) | catalogued as rs996024928; called by muse, mutect2
- B3GNT7 | c.*800G>A | 3'UTR (SNP) | VAF 42/75 reads (56%) | called by muse, mutect2, varscan2
- BCL7A | chr12:122021292 A>T | 5'Flank (SNP) | VAF 57/134 reads (43%) | called by muse, mutect2, varscan2
- BCL7A | chr12:122021402 C>G | 5'Flank (SNP) | VAF 80/173 reads (46%) | catalogued as rs925835724, COSV55846299, COSV55846759, COSV55847493; called by muse, varscan2
- BCL7A | chr12:122021526 A>G | 5'Flank (SNP) | VAF 86/213 reads (40%) | called by muse, varscan2
- BTBD3 | c.*1886T>C | 3'UTR (SNP) | VAF 66/122 reads (54%) | called by muse, mutect2, varscan2
- CAND1 | c.*6083T>G | 3'UTR (SNP) | VAF 56/105 reads (53%) | called by muse, mutect2, varscan2
- CASP4 | c.372+23T>C | Intron (SNP) | VAF 63/114 reads (55%) | catalogued as rs887708513; called by muse, mutect2, varscan2
- CD300LF | c.44-455_44-448del | Intron (DEL) | VAF 18/52 reads (35%) | called by mutect2, pindel, varscan2
- CDH26 | c.*403G>A | 3'UTR (SNP) | VAF 18/60 reads (30%) | called by muse, mutect2, varscan2
- DUSP16 | c.*78_*83del | 3'UTR (DEL) | VAF 91/103 reads (88%) | called by mutect2, pindel, varscan2
- EMP2 | c.*869G>A | 3'UTR (SNP) | VAF 41/312 reads (13%) | called by muse, mutect2, varscan2
- FASLG | c.*614T>A | 3'UTR (SNP) | VAF 4/28 reads (14%) | catalogued as rs975769386; called by muse, varscan2
- FOS | c.142-128A>C | Intron (SNP) | VAF 42/44 reads (95%) | called by muse, mutect2, varscan2
- FOXG1 | c.-31G>T | 5'UTR (SNP) | VAF 61/62 reads (98%) | catalogued as COSV100487096; called by muse, mutect2, varscan2
- HNRNPA0 | c.*1679T>A | 3'UTR (SNP) | VAF 23/55 reads (42%) | catalogued as rs889821915; called by muse, varscan2
- KMT2A | c.-14T>C | 5'UTR (SNP) | VAF 62/164 reads (38%) | called by muse, mutect2, varscan2
- LAMB2 | c.2489-129T>C | Intron (SNP) | VAF 29/41 reads (71%) | called by muse, mutect2, varscan2
- LGMN | c.*44G>A | 3'UTR (SNP) | VAF 111/242 reads (46%) | catalogued as rs377533058; called by muse, mutect2, varscan2
- LINC00587 | n.142T>A | RNA (SNP) | VAF 420/633 reads (66%) | called by muse, mutect2, varscan2
- LRRC15 | c.*2793C>G | 3'UTR (SNP) | VAF 59/207 reads (29%) | called by muse, mutect2, varscan2
- LRRC7 | c.100+37711G>C | Intron (SNP) | VAF 45/105 reads (43%) | called by muse, mutect2, varscan2
- LTB | c.162+124T>G | Intron (SNP) | VAF 25/64 reads (39%) | catalogued as COSV53001768; called by muse, mutect2, varscan2
- MBP | c.576+2264G>A | Intron (SNP) | VAF 36/64 reads (56%) | called by muse, mutect2, varscan2
- MIR5195 | chr14:106851206 del GTGGCCTTGGAAGGATGGGCT | 5'Flank (DEL) | VAF 96/135 reads (71%) | called by pindel, varscan2
- MIR5195 | chr14:106851340 T>A | 5'Flank (SNP) | VAF 96/106 reads (91%) | catalogued as rs188124295; called by muse, varscan2
- PDK1 | c.*93_*96del | 3'UTR (DEL) | VAF 60/160 reads (38%) | called by pindel, varscan2
- PEAK1 | c.*5054T>G | 3'UTR (SNP) | VAF 50/100 reads (50%) | called by muse, mutect2, varscan2
- PPIA | c.*1582T>A | 3'UTR (SNP) | VAF 181/187 reads (97%) | called by muse, mutect2, varscan2
- RCC1 | c.-270T>G | 5'UTR (SNP) | VAF 50/135 reads (37%) | called by muse, mutect2, varscan2
- SLC6A15 | c.*293A>C | 3'UTR (SNP) | VAF 29/56 reads (52%) | called by muse, mutect2, varscan2
- STPG2 | c.*1962A>T | 3'UTR (SNP) | VAF 32/90 reads (36%) | called by muse, mutect2, varscan2
- TINAG | c.-72C>T | 5'UTR (SNP) | VAF 44/110 reads (40%) | catalogued as COSV99450691; called by muse, mutect2, varscan2
